Somatic mutation profile of tumor specimen TARGET-20-PATELT-09A (aliquot TARGET-20-PATELT-09A-01D) from TARGET case TARGET-20-PATELT, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.0 years (4,401 days).
Specimen TARGET-20-PATELT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b273a49-d6cd-449f-a641-5e8247c32087.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATELT-10A (Blood Derived Normal), aliquot TARGET-20-PATELT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e37d27ab-bbe5-4d2a-b589-b1d8504ed5bb

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.278A>G p.K93R | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.55); called by muse, varscan2
- CROT | c.151A>G p.T51A | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); called by muse, varscan2
- DNAH8 | c.653A>G p.D218G | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- SMC3 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TAOK1 | c.1977G>A p.M659I | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.101); called by muse, varscan2
- FANCM | c.4947A>G p.L1649= | Silent (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
- PKNOX1 | c.1164G>A p.S388= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs531349610, COSV104394780; called by muse, mutect2, varscan2
- SCAPER | c.4152G>A p.Q1384= | Silent (SNP) | VAF 3/16 reads (19%) | called by muse, varscan2
- ZNF114 | c.75A>G p.P25= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, varscan2
